Somatic mutation profile of tumor specimen TARGET-20-PARVTI-09A (aliquot TARGET-20-PARVTI-09A-01D) from TARGET case TARGET-20-PARVTI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.2 years (4,469 days).
Specimen TARGET-20-PARVTI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 367c02b3-8f40-413e-8f98-fd58690cfed8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARVTI-14A (Bone Marrow Normal), aliquot TARGET-20-PARVTI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c913267-e3b6-4686-aeb5-2137ce7cbb80

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1096-1G>C p.X366_splice | Splice Site (SNP) | VAF 9/74 reads (12%) | catalogued as rs397517076, CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/149 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LCE2A | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as rs753692865, COSV64226821; called by muse, varscan2
- PTPRF | c.3311C>T p.P1104L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756648293; called by muse, mutect2, varscan2
- COL12A1 | c.4624G>A p.A1542T | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
